Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6528, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6528-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Multiple organ resection – stomach

TCGA – D7 – 6528

Physician in charge:

Material collected on Material received on

Expected time of examination:

Clinical diagnosis: Cancer of the stomach.

Examination performed on:

Macroscopic description:

Sent material containing the stomach, incised along the greater curvature, sized 21.8 x 13.4 cm with the omentum sized 29 x 22 cm. Tumour sized 9.8 x 6.4 x 2.8 cm found on the front wall. Distance from the proximal end 6.2 cm, from distal end 3.3 cm.

Microscopic description:

Adenocarcinoma tubulare invasivum ventriculi (G2).
(Lauren's intestinal type).

Neoplastic invasion covers the whole thickness of the wall, does not spread over the serous membrane, begins to infiltrate the omentum fat tissue.

Cut lines clear of neoplastic lesions.

Omentum - Hyperaemia

LYMPH NODES:

- periorificial - lymphonodis reactiva (No III).
- of lesser curvature - lymphonodis reactiva (No X).
- of greater curvature (R) - lymphonodis reactiva (No XIII).
- peripyloric - fat tissue, no reactive lymph nodes found.

Histopathological diagnosis:

Adenocarcinoma tubulare invasivum ventriculi (G2), pT2, pN0. Invasive tubular adenocarcinoma of the stomach.

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file a30f5037-f637-4be9-acb0-ed925a87d802 (TCGA-D7-6528.364D83CF-0B2E-4F18-9374-3E585140D016.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).